Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7380, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7380-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) SOFT TISSUE, SUPERIOR MEDIAL MARGIN, EXCISION: MATURE ADIPOSE TISSUE, SKELETAL MUSCLE, AND NERVE, NEGATIVE FOR MALIGNANCY.
- 2) SOFT TISSUE, PTERYGOID, EXCISION: INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 3) SOFT TISSUE, POSTERIOR SUPERIOR DEEP MARGIN, EXCISION: FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.
- 4) MUCOSA AND SUBMUCOSA, HARD PALATE MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 5) MUCOSA AND SUBMUCOSA, SOFT PALATE MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 6) PALATE, LEFT, MAXILLECTOMY: INVASIVE MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.2 CM IN GREATEST EXTENT, EXTENSIVELY INVOLVING THE MAXILLA AND SUPERFICIALLY ERODING INTO TOOTH ENAMEL, WITH EXTENSIVE PERINEURAL INVASION, PRESENT EXTENSIVELY AT THE SUPERIOR SURFACE AND ANTERIOR SURFACE Laterally; ANTERIOR AND POSTERIOR MAXILLARY BONE RESECTION SURFACES INVOLVED BY TUMOR.
- 7) SOFT TISSUE, INFRATEMPORAL MARGIN, LEFT, EXCISION: INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 8) BONE, MEDIAL, MAXILLECTOMY: INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 9) SOFT TISSUE, PTERYGOID PALATINE FOSSA, RESECTION: INVOLVED BY SQUAMOUS CELL CARCINOMA, INVASIVE INTO BONE.
- 10) SOFT TISSUE, DESCENDING PALATINE CANAL CONTENTS, EXCISION: INVOLVED BY SQUAMOUS CELL CARCINOMA WITH EXTENSIVE PERINEURAL INVASION.
- 11) SOFT TISSUE AND BONE, FINAL PTERYGOID MARGIN, EXCISION: BONE, BONE MARROW, AND SOFT TISSUE, NEGATIVE FOR MALIGNANCY.
- 12) LYMPH NODES, LEVELS 2 AND 3, LEFT, EXCISION: 17 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/17).

COMMENT: These findings correspond to AJCC 7th Edition pathologic Stage IVB (pT4b, pN0, M n/a).

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral

[page 2 of 5]
cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and
Hypopharynx Summary of Findings:

Specimen Type: left palate and maxillary bone

Tumor Site: soft and hard palate and maxilla

Tumor Size: 3.2 x 2.7 x 1.7 cm

Laterality: Left

Margin involved by invasive carcinoma - anterior and posterior maxillary
bone resection margins, deep margin, anterior portion of lateral surface

Histologic Type: squamous cell carcinoma

Histologic Grade: moderately differentiated

Pathologic Staging (pTMN): IVB

Primary tumor (pT): pT4b

Regional Lymph Nodes (pN): pN0

Number examined: 17

Numbered involved: 0

Perineural invasion: Yes

Bony/Cartilage Invasion: Yes

Lymphovascular invasion: No

HPV testing ordered: No

Electronically Signed Out by [REDACTED]

[REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)superior medial soft tissue margin;
2)pterygoid mass; 3)posterior superior
deep; 4)hard palate margin; 5)soft palate
margin; 6)left palate cancer; 7)left
infratemporal margin; 8)medial
maxillectomy; 9)pterygoid palatine fossa
resection; 10)descending palatine canal
contents; 11)final pterygoid margin;
12)left level 2, 3

GROSS DESCRIPTION:

[REDACTED]

[page 3 of 5]
1) SOURCE: Superior Medial Soft Tissue Margin

Received fresh for frozen section examination is a single piece of soft tissue and skeletal muscle measuring 1.2 x 0.8 x 0.4 cm. It is totally submitted.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Pterygoid Margin

Received fresh for frozen section examination is a single piece of soft tissue measuring 1.1 x 0.7 x 0.4 cm. It is totally submitted.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Posterior Superior Deep Margin

Received fresh for frozen section examination is a single piece of soft tissue measuring 1.2 x 0.7 x 0.5 cm. It is inked purple for identification. It is totally submitted.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Hard Palate Margin

Received fresh for frozen section examination is a single piece of mucosa and submucosal tissue measuring 2.1 x 1.0 x 0.3 cm. It is totally submitted.

Summary of sections: 4AFSC, 1/1.

5) SOURCE: Soft Palate Margin

Received fresh for frozen section examination is a single piece of mucosa and submucosal tissue measuring 5.5 x 0.5 x 0.2 cm. It is bisected and totally submitted.

Summary of sections: 5AFSC, 2/1.

6) SOURCE: Left Palate Cancer

Received fresh is a palate excision specimen showing a laterally placed portion of the maxilla with two teeth. The specimen measures 6.4 cm from anterior to posterior, 5.3 cm from medial to lateral, and 1.5 cm in maximal thickness. The maxillary bone measures 2.1 cm from anterior to posterior, 1.5 cm from superficial to deep, and 1.3 cm from medial to lateral. The mucosal surface shows an ulcerated, slightly raised lesion with irregular nodular surface measuring 3.2 cm from anterior to posterior and 2.7 cm from medial to lateral. The lesion appears to involve the two teeth that are resected and might involve the maxillary bone. The anterior resection margin is irregular and curved posteriorly as it approaches the more anterior molar. This margin passes through the raised, irregular ulcerated area. The anterior edge of the specimen, including the anterior edge of the bone and soft tissue, is inked blue. The posterior margin of the specimen is inked black. The medial edge is inked green. The lateral edge, which shows mucosa, soft tissue, and salivary gland, is inked orange. The deep resection surface corresponding to the roof of the palate is inked purple. Serial sectioning through the mass shows the mass to involve the maxillary

[page 4 of 5]
bone surrounding the teeth. The mass appears to be present at the deep margin multifocally. Representative sections are submitted as follows.

Cassettes 6E, 6G, and 6I are decalcified.

Summary of sections: 6A, anterior margin, perpendicularly sectioned, M/1; 6B-6D, serial section adjacent to anterior margin from anterior to posterior showing the resection margin that dips posteriorly, inked blue, 2/1 each; 6E-6F, anterior bony resection margin and associated section through the entire lesion from medial to lateral, 1/1 each; 6G-6H, complete section from medial to lateral showing the entire lesion involving bone and tooth as well as being close to margin, 1/1 each; 6I-6J, section from medial to lateral directly adjacent to those present in 6G and 6H, 1/1 each; 6K-6L, posterior bony resection margin incorporated from medial to lateral sections showing the entire specimen from medial to lateral, 2/1 each; 6M-6N, posterior margin perpendicular sectioned, M/1 each.

7) SOURCE: Left Infratemporal Margin

Received fresh are two pieces of mucosa and submucosal tissue, the larger measuring 2.1 cm in length and the shorter measuring 1.1 cm in length. Also present in the container is a piece of adipose tissue measuring 2.2 x 1.2 x 0.2 cm. The tissue is totally submitted.

Summary of sections: 7A, 3/1.

8) SOURCE: Medial Maxillectomy

Received fresh is a piece of cartilage and thin bone measuring 3.2 x 1.5 x 0.1 cm. There is a perpendicular piece of soft tissue projecting off one edge of this lesion and measures 0.7 cm in height and 1.2 x 0.2 cm in other dimensions. The tissue is serially sectioned and totally submitted.

Summary of sections: 8A, 6/1.

9) SOURCE: Pterygoid Palatine Fossa Resection

Received fresh are multiple fragments of thin bony as well as soft tissue measuring in aggregate 2.3 x 1.5 x 0.4 cm. They are totally submitted after decalcification.

Summary of sections: 9A, M/1.

10) SOURCE: Descending Palatine Canal Contents

Received fresh is a segment of firm tissue measuring 1.2 x 0.3 x 0.2 cm and showing two metallic clips, which are removed and the specimen is totally submitted after being bisected.

Summary of sections: 10A, 2/1.

11) SOURCE: Final Pterygoid Margin

Received fresh are two pieces of soft tissue measuring 1.3 x 1.5 x 0.4 cm in aggregate. They are totally submitted.

Summary of sections: 11A, 2/1.

12) SOURCE: Left Level 2,3

Received fresh is a piece of fatty tissue containing nodules and measuring

[page 5 of 5]
9.5 x 3.5 x 1.2 cm. The candidate lymph nodes are dissected and totally submitted.

Summary of sections: 12A, two largest lymph nodes, each bisected, 4/1; 12B-12D, candidate nodes, M/1 each.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Superior Medial Soft Tissue Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

2) SOURCE: Pterygoid Margin

FROZEN SECTION DIAGNOSIS: INVOLVED BY CARCINOMA. [REDACTED]

3) SOURCE: Posterior Superior Deep Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Hard Palate Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

5) SOURCE: Soft Palate Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED]

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

2xDECALCIFICATION

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA [REDACTED]) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 82ca2511-8921-41ad-8d23-a25f2379e480 (TCGA-CR-7380.C02B9D89-DF9F-4828-848C-B50A1FCD3C1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).